Somatic mutation profile of tumor specimen TCGA-DX-A3U6-01A (aliquot TCGA-DX-A3U6-01A-11D-A29N-09) from TCGA case TCGA-DX-A3U6, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.5 years (23,193 days).
Specimen TCGA-DX-A3U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1179f01f-20a1-4d88-ba52-a30ac93761d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3U6-10A (Blood Derived Normal), aliquot TCGA-DX-A3U6-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a5a809b-d25b-4334-afb5-d74ce21d29e4

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RDH16 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs764532243; called by muse, mutect2, varscan2
- SMC6 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100704984; called by mutect2, varscan2
- FIBCD1 | c.1284C>T p.H428= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs757657652, COSV99446865; called by mutect2, varscan2
